Somatic mutation profile of tumor specimen ALCH-ABOK-TTP1-A (aliquot ALCH-ABOK-TTP1-A-1-0-D-A488-36) from ALCHEMIST case ALCH-ABOK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,573 days).
Specimen ALCH-ABOK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6f8fb8d-5674-4d0f-a434-08bf2a5edc4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABOK-NB1-A (Blood Derived Normal), aliquot ALCH-ABOK-NB1-A-1-0-D-A488-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ce7262d-3f7f-4c5a-a67e-ff8473f0d5b4

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Intron 4, 3'Flank 2, In Frame Del 1, Frame Shift Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs750175676; called by muse, mutect2, varscan2
- BTBD11 | c.1069_1071del p.N357del | In Frame Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs1426988172; called by pindel, varscan2
- CFAP69 | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774844602; called by muse, mutect2, varscan2
- KCNH8 | c.2224G>T p.V742F | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs748160540; called by muse, mutect2
- KCP | c.3920C>T p.A1307V (on ENST00000620378; = p.A1431V on NM_001366122.1) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs200366368; called by muse, mutect2, varscan2
- LCN10 | c.536C>T p.A179V (on ENST00000474369 / NM_001368089.1; = p.A192V on NM_001001712.3) | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs751195542; called by muse, mutect2, varscan2
- LRRC49 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as rs1363357837; called by muse, mutect2, varscan2
- OPN1MW | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 196/1288 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs782096753; called by muse, mutect2, varscan2
- OR2W1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745574396, COSV65851508; called by muse, mutect2, varscan2
- OSGEP | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768795595; called by muse, mutect2, varscan2
- RNASEH1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs201353590; called by muse, mutect2, varscan2
- CCN1 | c.584A>C p.N195T | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GMEB1 | c.1612A>C p.K538Q | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.53); called by muse, mutect2
- GTF3C6 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by mutect2, varscan2
- KNTC1 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LAMA3 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGI3 | c.1642T>G p.L548V | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MEX3B | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- NAA20 | c.453T>C p.D151= | Splice Region (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.931T>A p.W311R | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL11 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PAK2 | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1132T>C p.F378L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBL2 | c.636A>T p.K212N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF213 | c.6227del p.L2076Yfs*4 | Frame Shift Del (DEL) | VAF 29/240 reads (12%) | called by mutect2, pindel, varscan2
- RSRC2 | c.875A>C p.Q292P | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIDT2 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SIDT2 | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SMG1 | c.307T>C p.S103P | Missense Mutation (SNP) | VAF 77/467 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- TTL | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UBA7 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACACA | c.1248T>C p.S416= | Silent (SNP) | VAF 67/395 reads (17%) | called by muse, mutect2, varscan2
- CACNB2 | c.1881T>C p.R627= (on ENST00000324631 / NM_201596.3; = p.R572= on NM_000724.4) | Silent (SNP) | VAF 44/180 reads (24%) | called by muse, mutect2, varscan2
- FAM160A2 | c.510A>C p.P170= | Silent (SNP) | VAF 29/226 reads (13%) | called by muse, mutect2, varscan2
- FAM180A | c.273C>T p.T91= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs928585097, COSV58528278; called by muse, mutect2
- HEMK1 | c.384C>T p.P128= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- LAMA4 | c.828C>T p.C276= (on ENST00000230538 / NM_001105206.3; = p.C269= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/426 reads (3%) | catalogued as rs782380339, COSV57896505; ClinVar: likely benign; called by muse, mutect2
- TRIM61 | c.567G>A p.T189= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1171388471; called by muse, mutect2, varscan2
- ACBD5 | chr10:27195374 A>T | 3'Flank (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- ATP6AP2 | c.-88G>A | 5'UTR (SNP) | VAF 41/306 reads (13%) | called by muse, mutect2, varscan2
- DNM2 | c.1558-152A>G | Intron (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- DRC1 | c.679-253G>A | Intron (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- PTPN6 | c.8+22T>C | Intron (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- RPS3A | c.355-813_355-806del | Intron (DEL) | VAF 19/114 reads (17%) | called by mutect2, pindel, varscan2
- SYT14 | chr1:210162700 T>A | 3'Flank (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
